Somatic mutation profile of tumor specimen MP2PRT-PAUFHH-TMP1-A (aliquot MP2PRT-PAUFHH-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PAUFHH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,045 days).
Specimen MP2PRT-PAUFHH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da153418-e87b-42ea-ab67-dfb713e0b569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUFHH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUFHH-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9cf94583-708f-4b7d-9e7d-d77244b1d35a

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 36/338 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 48/322 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNMA1 | c.2675C>T p.T892M (on ENST00000286628 / NM_001161352.2; = p.T834M on NM_002247.4) | Missense Mutation (SNP) | VAF 59/359 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as rs200440843, COSV54269078; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA4 | c.1420G>A p.V474I (on ENST00000230538 / NM_001105206.3; = p.V467I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/411 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.047); catalogued as rs375981026; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MOAP1 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 75/826 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs143399910; called by muse, mutect2
- SIPA1L3 | c.4490G>A p.R1497Q | Missense Mutation (SNP) | VAF 70/336 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs767194859; called by muse, mutect2, varscan2
- CALML5 | c.212C>A p.T71K | Missense Mutation (SNP) | VAF 71/687 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FAM170B | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 92/535 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- IFT88 | c.1358dup p.D454Gfs*3 (on ENST00000319980 / NM_001318493.2; = p.D445Gfs*3 on NM_006531.5 and 9 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 50/232 reads (22%) | called by mutect2, varscan2
- IGKV2D-24 | chr2:90005628 CTCA>GCTCCTCTT | Missense Mutation (INS) | VAF 32/168 reads (19%) | called by pindel, varscan2*
- LIG3 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 38/345 reads (11%) | called by muse, mutect2, varscan2
- MED24 | c.2033T>A p.L678Q | Missense Mutation (SNP) | VAF 79/500 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- OR1S2 | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 64/382 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PLBD2 | c.1588G>A p.G530S | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CIDEA | c.636C>T p.A212= | Silent (SNP) | VAF 60/344 reads (17%) | catalogued as rs149874934; called by muse, mutect2, varscan2
- ETNPPL | c.84G>A p.S28= | Silent (SNP) | VAF 59/296 reads (20%) | catalogued as rs748968101, COSV56597460; called by muse, mutect2, varscan2
- JAKMIP1 | c.1500C>T p.R500= | Silent (SNP) | VAF 159/566 reads (28%) | catalogued as rs149678000; called by muse, mutect2, varscan2
- SNPH | c.795G>A p.S265= | Silent (SNP) | VAF 99/540 reads (18%) | catalogued as rs537448470, COSV60590980; called by muse, mutect2, varscan2
